Gene-level copy-number profile of tumor specimen TCGA-A2-A3XZ-01A from TCGA case TCGA-A2-A3XZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 46.5 years (16,978 days).
Specimen TCGA-A2-A3XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7a55f6a3-a438-418f-a5a8-dcea12c977d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A3XZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e922769-903a-4693-b57c-d262a9487c1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 6,690; copy number 2: 39,934; copy number 3: 8,786; copy number 4: 4,001; copy number 5: 62; copy number 10: 8; copy number 11: 24; copy number 13: 33; copy number 14: 19; copy number 18: 81; copy number 37: 95; copy number 40: 49; copy number 47: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A3XZ-01A-42D-A238-01): tumor purity 0.27, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:166,312,935–168,187,736, 11 genes (within-gene range 0–1): Y_RNA, AC097487.1, SPOCK3, RNA5SP171, AC079349.1, RN7SL776P, PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10.
- chr4:176,631,392–177,362,936, 10 genes: AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509, RN7SKP136, AC097518.1, NEIL3, AC027627.1.
- chr4:180,095,527–181,591,969, 8 genes: AC096747.1, NDUFB5P1, AC104803.1, LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 378 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:39,027,277–41,140,487, 114 genes, copy number 14–37 (within-gene range 2–37) (broad region; genes not listed).
- chr17:49,132,460–53,106,358, 117 genes, copy number 10–47 (broad region; genes not listed).
- chr17:53,353,427–53,439,721, 3 genes, copy number 47: AC005341.1, AC090079.1, AC090079.2.
- chr17:59,619,689–60,666,280, 46 genes, copy number 40 (within-gene range 1–40): CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,696,313–60,749,046, 3 genes, copy number 40: RN7SL606P, AC110602.1, Y_RNA.
- chr17:66,267,743–67,697,261, 33 genes, copy number 13 (within-gene range 2–13): RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3.
- chr17:72,021,851–73,236,753, 22 genes, copy number 5: ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A.
- chr19:21,020,634–21,329,425, 16 genes, copy number 5 (within-gene range 1–5): ZNF430, AC008739.3, VN1R80P, ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10, VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25.
- chr19:22,974,883–23,416,075, 24 genes, copy number 5: ZNF728, BNIP3P36, LINC01859, LINC01858, AC074135.2, AC074135.1, ZNF730, BNIP3P37, AC124856.1, SNX6P1, AC092329.2, ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224.

Autosomal genes at a single copy (total copy number 1): 6,690. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
